Somatic mutation profile of tumor specimen 0DIMWY from CCDI case PBBVNP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 7.3 years (2,679 days).
Specimen 0DIMWY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e68e765c-cc42-47ef-a417-60b700b9b522.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79f6b72d-d912-437b-b5a8-9a71ed407081

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 1, Intron 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 721/776 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CAMSAP2 | c.943G>A p.A315T (on ENST00000236925 / NM_001297707.2; = p.A304T on NM_203459.3) | Missense Mutation (SNP) | VAF 128/372 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs776680010; called by muse, mutect2
- FAM71F2 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 152/376 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV101100653, COSV101100726; called by muse, mutect2, varscan2
- FCGR3B | c.10C>A p.L4M | Missense Mutation (SNP) | VAF 195/240 reads (81%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs1271845437; called by muse, mutect2, varscan2
- MTMR7 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 38/1052 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs968622478, COSV51663038; called by muse, mutect2
- MYBPC2 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs749460100, COSV63098114, COSV63098169; called by muse, mutect2, varscan2
- SAMD9 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 248/647 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs200748623, COSV101180323, COSV66075697; called by muse, mutect2, varscan2
- SLIT1 | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1046200407, COSV56599634; called by muse, mutect2, varscan2
- CKB | c.778-1_778del p.X260_splice | Splice Site (DEL) | VAF 61/229 reads (27%) | called by mutect2, pindel, varscan2
- POP1 | c.802G>T p.G268* | Nonsense Mutation (SNP) | VAF 96/537 reads (18%) | called by muse, mutect2, varscan2
- CCL21 | c.357C>A p.S119= | Silent (SNP) | VAF 224/595 reads (38%) | called by muse, mutect2, varscan2
- IGFLR1 | c.738G>A p.A246= | Silent (SNP) | VAF 88/263 reads (33%) | catalogued as rs776036027, COSV53074308; called by muse, mutect2, varscan2
- RUNX1 | c.918G>A p.P306= (on ENST00000344691 / NM_001001890.3; = p.P333= on NM_001754.5) | Silent (SNP) | VAF 132/355 reads (37%) | catalogued as COSV55877461; called by muse, mutect2, varscan2
- CELF2 | c.54-186G>A | Intron (SNP) | VAF 164/384 reads (43%) | catalogued as rs1257432912, COSV59983162; called by muse, mutect2, varscan2
- POFUT2 | c.*75G>A | 3'UTR (SNP) | VAF 36/91 reads (40%) | catalogued as rs930702952; called by muse, mutect2, varscan2
